Somatic mutation profile of tumor specimen 0DKRCY from CCDI case PBBXFC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 8.8 years (3,229 days).
Specimen 0DKRCY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b00fbab-ac72-4766-b54f-9065b9f5dfb0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKRC9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77967d8f-347b-4883-882d-a35abeef9ff3

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Nonsense Mutation 1, Silent 1, Intron 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.933C>G p.I311M | Missense Mutation (SNP) | VAF 18/378 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61370042; called by muse, mutect2
- BAZ1B | c.1046C>A p.S349* | Nonsense Mutation (SNP) | VAF 44/1379 reads (3%) | catalogued as COSV59989381; called by muse, mutect2
- TMX2 | c.96C>A p.L32= | Silent (SNP) | VAF 112/826 reads (14%) | called by muse, varscan2
- MSRB3 | c.98-18272G>A | Intron (SNP) | VAF 64/525 reads (12%) | catalogued as rs773522857; called by muse, mutect2, varscan2
